Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4638, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4638-01A (Primary Tumor).

Tissue Source Site (

Pathology Accession

Pathology Report

DIAGNOSIS

TCGA - CJ - 4638

(A) LEFT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 4 (15.0 CM).

(SEE COMMENT)

TUMOR FOCALLY INVADES RENAL SINUS FAT.

TUMOR INVADING THE RENAL VEIN. RENAL VEIN MARGIN OF RESECTION FREE OF TUMOR.

METASTATIC RENAL CELL CARCINOMA INVOLVING WALL OF DISTAL PORTION OF URETER.

URETERAL MARGIN OF RESECTION FREE OF TUMOR.

METASTATIC RENAL CELL CARCINOMA IN MATTED HILAR LYMPH NODES (APPROXIMATELY TWENTY).

Three additional hilar lymph nodes, no tumor present.

Adrenal gland, no tumor present.

(B) NODE BELOW THE BIFURCATION:

METASTATIC RENAL CELL CARCINOMA INVOLVING ONE LYMPH NODE .

COMMENT

The tumor displays focally rhabdoid features.

GROSS DESCRIPTION

(A) LEFT KIDNEY - A radical nephrectomy specimen (18.0 cm x 17.0 cm x 10 cm), including a kidney (16.0 cm x 9.0 cm x 10.0 cm), ureter (12.0 cm x 0.5 cm), hilar lymph nodes (measuring overall 15.0 x 6.0 x 6.0 cm), and adrenal gland (4.0 x 1.5 x 0.5 cm).

A well-circumscribed tumor (15.0 x 8.5 x 9.0 cm) is present occupying approximately 90% of the renal parenchyma. It is yellow tan with extensive areas of hemorrhage and necrosis. The tumor appears to invade the renal sinus and renal vein, however, the renal vein margin is free of tumor. The tumor does not appear to extend into the perirenal fat margin. The pelvis appears nodular but has a smooth surface. The kidney parenchyma away from tumor shows multiple tumor nodules. One centimeter from the ureteral margin is a 0.2 cm cystic nodule. The ureteral margin is grossly free of tumor.

The renal hilum is expanded (15.0 x 6.0 x 6.0 cm) and contains multiple matted lymph nodes (approximate total of 23), most of which are grossly involved by tumor.

The adrenal gland appears uninvolved by tumor.

INK CODE: Black - soft tissue margin.

SECTION CODE: A1, renal vein and ureteral margins; A2-A5, tumor in sinus and pelvis; A6, tumor and perinephric fat margin; A7-A8 tumor in renal vein; A9-A10, tumor; A11-A12, tumor and adjacent kidney parenchyma; A13-A18, lymph nodes; A19, normal kidney; A20, adrenal gland; A21, three unremarkable lymph nodes entirely submitted; A22, lesion 1 cm from ureteral margin.

(B) NODE BELOW THE BIFURCATION - A lymph node (4.0 cm x 2.2 cm x 2.0 cm) grossly involved by tumor.

SECTION CODE: B1-B2, representative sections of lymph node.

CLINICAL HISTORY

None given.

Source: NCI Genomic Data Commons file 9f704e15-b78f-4001-9311-390b764a786f (TCGA-CJ-4638.BD0ACE3D-3A81-4DE7-8283-C87C9942CC92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).